Gene-level copy-number profile of tumor specimen TCGA-36-2544-01A from TCGA case TCGA-36-2544, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.5 years (21,384 days).
Specimen TCGA-36-2544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2f63f98f-8eb2-4bce-89c5-b5a7e9b6218c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2544-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7928865f-a397-402f-8297-53d085d41efa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 11,955; copy number 2: 38,336; copy number 3: 8,207; copy number 4: 1,185; copy number 5: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2544-01A-01D-1043-01): tumor purity 0.91, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,751,232–1,891,117, 2 genes (within-gene range 0–2): NADK, GNB1.
- chr9:21,058,771–26,805,862, 83 genes (broad region; genes not listed).
- chr22:46,761,894–49,377,119, 30 genes: AL118516.1, TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2, TAFA5, Z84468.1, MIR4535, LINC01310, AL078622.1, Z82202.2, RPL35P8, Z82202.1, AC207130.1.
- chr22:49,500,568–49,501,585, 1 gene: AL008636.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:49,918,503–51,225,575, 6 genes, copy number 5 (within-gene range 3–5): NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1.

Autosomal genes at a single copy (total copy number 1): 11,948. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
